Somatic mutation profile of tumor specimen HCM-BROD-0027-C34-06A (aliquot HCM-BROD-0027-C34-06A-11D-A786-36) from HCMI case HCM-BROD-0027-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G3; Age at diagnosis: 65.4 years (23,897 days).
Specimen HCM-BROD-0027-C34-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54156544-de99-41f7-b09d-86ecd1c22d5b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0027-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0027-C34-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/585d0bef-6e9e-428e-b6e9-73b17866b368

The open-access MAF lists 2,824 somatic variants for this specimen: 1,953 protein-altering or splice-affecting, 542 silent, 329 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,649, Silent 542, Intron 145, Nonsense Mutation 145, Frame Shift Del 65, RNA 57, Splice Site 53, 5'UTR 47, 3'UTR 37, 5'Flank 29, Splice Region 21, 3'Flank 14.

Variants (750 of 2,824; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 94/263 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PMS2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 209/853 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1554309086; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RAG1 | c.527G>T p.C176F | Missense Mutation (SNP) | VAF 48/333 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs149229197; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- STK11 | c.658C>T p.Q220* | Nonsense Mutation (SNP) | VAF 97/186 reads (52%) | hotspot (GDC flag); catalogued as rs1131690940, CM991157, COSV58820792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 234/786 reads (30%) | hotspot (GDC flag); catalogued as rs201744589, CM031387, COSV52661551, COSV52761493, COSV53353479, COSV53790595; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A1CF | c.1129C>A p.P377T | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.073); catalogued as COSV50959538; called by muse, mutect2, varscan2
- ABCA4 | c.523G>T p.D175Y | Missense Mutation (SNP) | VAF 205/479 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV64674465; called by muse, mutect2, varscan2
- ABCA8 | c.262C>A p.Q88K | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs1391761692, COSV52207765; called by muse, mutect2, varscan2
- ABCA9 | c.2860C>T p.P954S | Missense Mutation (SNP) | VAF 65/201 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.023); catalogued as COSV100383519; called by muse, mutect2, varscan2
- ABCD1 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs889290843, CD011858, CM105292; called by muse, mutect2, varscan2
- AC018709.1 | c.191G>A p.C64Y | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.922); catalogued as rs770383744; called by muse, mutect2, varscan2
- ACADSB | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.136); catalogued as COSV100715195; called by muse, mutect2, varscan2
- ACAN | c.848C>A p.T283K | Missense Mutation (SNP) | VAF 70/244 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749047801, COSV100716994; called by muse, mutect2, varscan2
- ACAN | c.6404C>A p.A2135E | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100718317; called by muse, mutect2
- ACAN | c.6883G>T p.E2295* | Nonsense Mutation (SNP) | VAF 95/348 reads (27%) | catalogued as rs1334745093, COSV61357872; called by muse, mutect2, varscan2
- ACKR2 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 43/287 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as rs1022451688; called by muse, mutect2, varscan2
- ACSL4 | c.1417G>T p.G473C (on ENST00000340800 / NM_022977.2; = p.G432C on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61615123; called by muse, mutect2, varscan2
- ADAM29 | c.857C>A p.S286* | Nonsense Mutation (SNP) | VAF 12/23 reads (52%) | catalogued as COSV100822231, COSV63664359; called by muse, mutect2, varscan2
- ADAMTS16 | c.3026G>T p.R1009L | Missense Mutation (SNP) | VAF 114/391 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99068537, COSV99940840; called by muse, mutect2, varscan2
- ADAMTS2 | c.1312C>G p.L438V | Missense Mutation (SNP) | VAF 165/535 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV51077696; called by muse, mutect2, varscan2
- ADAMTS6 | c.1310C>G p.A437G | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.46); catalogued as COSV66862422; called by muse, mutect2, varscan2
- ADGB | c.2173G>A p.G725S | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV58857958; called by muse, mutect2, varscan2
- ADGRA1 | c.946C>A p.H316N | Missense Mutation (SNP) | VAF 182/562 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV63416446; called by muse, varscan2
- ADGRG4 | c.1633T>C p.S545P | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99796053; called by muse, mutect2, varscan2
- ADGRV1 | c.10811C>T p.T3604I | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as rs1228940279; called by muse, mutect2, varscan2
- AFAP1L2 | c.456C>A p.D152E | Missense Mutation (SNP) | VAF 75/471 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58415631; called by muse, mutect2, varscan2
- AFP | c.838G>A p.D280N | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as COSV56925041; called by muse, mutect2, varscan2
- AHNAK2 | c.11464A>G p.I3822V | Missense Mutation (SNP) | VAF 204/468 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs779675075; called by muse, mutect2, varscan2
- AKAP14 | c.13C>A p.Q5K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57629397; called by muse, mutect2, varscan2
- AKAP6 | c.5044G>A p.E1682K | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as COSV55215860; called by muse, mutect2, varscan2
- ALDH7A1 | c.1093+1G>T p.X365_splice | Splice Site (SNP) | VAF 78/260 reads (30%) | catalogued as CS106148, COSV63160839; called by muse, mutect2, varscan2
- ALX1 | c.485G>C p.R162T | Missense Mutation (SNP) | VAF 95/263 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV57492123; called by muse, mutect2, varscan2
- ANKMY1 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 123/414 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.024); catalogued as COSV56034837; called by muse, mutect2, varscan2
- ANKRD31 | c.970G>T p.E324* | Nonsense Mutation (SNP) | VAF 33/68 reads (49%) | catalogued as COSV57163915; called by muse, mutect2
- ANKRD33B | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 172/492 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.035); catalogued as COSV56978526; called by muse, mutect2, varscan2
- ANKRD36 | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 65/251 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs768292033; called by muse, mutect2, varscan2
- ANO7 | c.959G>T p.W320L (on ENST00000274979; = p.W266L on NM_001370694.2) | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51469496; called by muse, mutect2, varscan2
- APBA2 | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 54/147 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.297); catalogued as COSV68794051; called by muse, mutect2
- AR | c.1705G>T p.G569W | Missense Mutation (SNP) | VAF 94/234 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1555982864, CM942023, COSV101018580, COSV65965227; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF28 | c.1222A>T p.T408S | Missense Mutation (SNP) | VAF 61/287 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs777570044; called by muse, mutect2, varscan2
- ARMC4 | c.2522G>C p.R841P | Missense Mutation (SNP) | VAF 66/260 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV59462487; called by muse, mutect2, varscan2
- ASB10 | c.281G>C p.R94P | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as CM121521; called by muse, mutect2, varscan2
- ASPM | c.4978A>G p.I1660V | Missense Mutation (SNP) | VAF 65/247 reads (26%) | SIFT tolerated (0.58); PolyPhen benign (0.009); catalogued as rs1279540274; called by muse, mutect2, varscan2
- ATP13A4 | c.2843-1G>C p.X948_splice | Splice Site (SNP) | VAF 66/250 reads (26%) | catalogued as COSV61317337; called by muse, mutect2, varscan2
- ATP2A1 | c.2661C>A p.D887E | Missense Mutation (SNP) | VAF 147/477 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV62869174; called by muse, mutect2, varscan2
- ATP2B4 | c.2936G>T p.R979L | Missense Mutation (SNP) | VAF 83/344 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58181232; called by muse, mutect2, varscan2
- ATRNL1 | c.1712C>A p.P571Q | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV61801934, COSV61805324; called by muse, mutect2
- B3GAT3 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 126/427 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV99605846; called by muse, mutect2, varscan2
- BCORL1 | c.2723G>T p.C908F | Missense Mutation (SNP) | VAF 60/229 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54395122; called by muse, mutect2, varscan2
- BMS1 | c.3756G>T p.K1252N | Missense Mutation (SNP) | VAF 72/247 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65733691; called by muse, mutect2, varscan2
- BRAT1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 119/365 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as COSV100500692; called by muse, mutect2, varscan2
- BRINP1 | c.985C>A p.H329N | Missense Mutation (SNP) | VAF 224/541 reads (41%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.775); catalogued as COSV99775790; called by muse, mutect2, varscan2
- BRINP3 | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 63/208 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.202); catalogued as COSV100818385, COSV66540992; called by muse, mutect2, varscan2
- BRIP1 | c.3342G>C p.Q1114H | Missense Mutation (SNP) | VAF 70/228 reads (31%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV52007379; called by muse, mutect2, varscan2
- BTNL2 | c.471G>T p.E157D | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.049); catalogued as rs1237317131; called by muse, mutect2
- C7 | c.1373G>T p.R458L | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.065); catalogued as rs369303619; called by muse, mutect2, varscan2
- C8orf33 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.05); catalogued as rs571241836; called by muse, mutect2, varscan2
- CA10 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 60/250 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as COSV53342713; called by muse, mutect2, varscan2
- CACNA1F | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 173/536 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as rs782667611, COSV59903430; called by muse, mutect2, varscan2
- CACNA2D4 | c.2306G>A p.S769N | Missense Mutation (SNP) | VAF 76/347 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.072); catalogued as rs1383838548; called by muse, mutect2, varscan2
- CACNG5 | c.12C>A p.C4* | Nonsense Mutation (SNP) | VAF 39/137 reads (28%) | catalogued as rs138908277; called by muse, varscan2
- CAMSAP2 | c.3890G>T p.G1297V (on ENST00000236925 / NM_001297707.2; = p.G1286V on NM_203459.3) | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.343); catalogued as COSV52667156; called by muse, mutect2, varscan2
- CAPN14 | c.940G>A p.G314R | Missense Mutation (SNP) | VAF 85/327 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767915234; called by muse, mutect2, varscan2
- CAPN9 | c.615G>C p.E205D | Missense Mutation (SNP) | VAF 86/263 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99680251; called by muse, mutect2, varscan2
- CBFB | c.399+1G>T p.X133_splice | Splice Site (SNP) | VAF 53/150 reads (35%) | catalogued as COSV51998595, COSV52002396; called by muse, mutect2, varscan2
- CBLN1 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 79/474 reads (17%) | catalogued as COSV54654945; called by muse, mutect2, varscan2
- CCDC168 | c.17919C>A p.N5973K | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); catalogued as COSV59422514; called by muse, mutect2, varscan2
- CCDC39 | c.1722G>C p.M574I | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as COSV56479520; called by muse, mutect2, varscan2
- CCDC39 | c.1159G>T p.D387Y | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs1452983069, COSV56490167, COSV99870496; called by muse, mutect2, varscan2
- CCL4 | c.12C>G p.C4W | Missense Mutation (SNP) | VAF 131/447 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs199619169; called by muse, mutect2, varscan2
- CCNG2 | c.13G>T p.G5W | Missense Mutation (SNP) | VAF 51/153 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as rs1560421219; called by muse, mutect2, varscan2
- CCT8L2 | c.1157G>T p.R386L | Missense Mutation (SNP) | VAF 47/467 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.499); catalogued as COSV100743070; called by muse, mutect2, varscan2
- CD5L | c.868T>A p.S290T | Missense Mutation (SNP) | VAF 200/624 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV100941227; called by muse, mutect2, varscan2
- CDC73 | c.440G>T p.R147L | Missense Mutation (SNP) | VAF 72/288 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100813823; called by muse, mutect2, varscan2
- CDH11 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as COSV51752428; called by muse, mutect2, varscan2
- CDH13 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51799039; called by muse, mutect2, varscan2
- CDK14 | c.947+1G>T p.X316_splice (on ENST00000380050 / NM_001287135.2; = p.X298_splice on NM_012395.3) | Splice Site (SNP) | VAF 64/204 reads (31%) | catalogued as COSV56033551, COSV56033914; called by muse, varscan2
- CEACAM21 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 107/443 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781931004; called by muse, mutect2, varscan2
- CEACAM8 | c.614T>A p.V205D | Missense Mutation (SNP) | VAF 248/719 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754846441; called by muse, mutect2, varscan2
- CEP164 | c.2434G>T p.G812W | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV54037796; called by muse, mutect2
- CES4A | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV58653556, COSV58654966; called by muse, mutect2, varscan2
- CFAP47 | c.8117C>G p.P2706R | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV66218239; called by muse, mutect2, varscan2
- CHRNA4 | c.1667C>T p.P556L | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.025); catalogued as rs77345643; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CLDN17 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 144/329 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV54523139; called by muse, mutect2, varscan2
- CLDN2 | c.560C>T p.S187F | Missense Mutation (SNP) | VAF 77/328 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.071); catalogued as rs377500294; called by muse, mutect2, varscan2
- CMTR2 | c.346T>C p.C116R | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100579318; called by muse, mutect2, varscan2
- CMYA5 | c.7079C>G p.S2360C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV71409742; called by mutect2, varscan2
- CNGB3 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 102/429 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.43); catalogued as COSV60691538; called by muse, mutect2, varscan2
- CNTNAP4 | c.835C>G p.R279G | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as COSV56670919; called by muse, mutect2, varscan2
- CNTNAP5 | c.673C>T p.R225C | Missense Mutation (SNP) | VAF 37/327 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs775327117, COSV70494830; called by muse, mutect2, varscan2
- CNTNAP5 | c.2805G>T p.L935F | Missense Mutation (SNP) | VAF 67/251 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV70507425; called by muse, mutect2, varscan2
- COL11A1 | c.3856C>A p.P1286T | Missense Mutation (SNP) | VAF 59/441 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as COSV62175639; called by muse, mutect2, varscan2
- COL11A1 | c.907G>T p.V303F | Missense Mutation (SNP) | VAF 67/162 reads (41%) | SIFT tolerated (0.71); PolyPhen benign (0.308); catalogued as COSV62173608; called by muse, mutect2, varscan2
- COL11A1 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1312249178; called by muse, mutect2, varscan2
- COL16A1 | c.1620G>T p.R540S | Missense Mutation (SNP) | VAF 25/169 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV54713504; called by muse, mutect2, varscan2
- COL22A1 | c.3817G>T p.G1273C | Missense Mutation (SNP) | VAF 40/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57328946; called by muse, mutect2, varscan2
- COL3A1 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 87/355 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.395); catalogued as rs1559056438; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A2 | c.3823C>T p.L1275F | Missense Mutation (SNP) | VAF 184/667 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs570175207; called by muse, mutect2, varscan2
- COL8A1 | c.1984T>A p.Y662N | Missense Mutation (SNP) | VAF 73/232 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs201189348; called by muse, mutect2, varscan2
- COL9A1 | c.1610C>A p.T537K | Missense Mutation (SNP) | VAF 144/554 reads (26%) | SIFT tolerated (0.77); PolyPhen benign (0.25); catalogued as COSV57888254; called by muse, mutect2, varscan2
- COL9A3 | c.700C>G p.R234G | Missense Mutation (SNP) | VAF 139/493 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs1027769042, COSV59650362; called by muse, mutect2, varscan2
- CPB1 | c.1234G>T p.V412F | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV51577232; called by muse, mutect2, varscan2
- CPXM2 | c.1512G>T p.W504C | Missense Mutation (SNP) | VAF 151/457 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99582189; called by muse, mutect2, varscan2
- CR2 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 70/302 reads (23%) | catalogued as rs539720446; called by muse, mutect2, varscan2
- CRACD | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 118/336 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV51719576; called by muse, mutect2, varscan2
- CRAMP1 | c.3179C>T p.S1060L | Missense Mutation (SNP) | VAF 129/428 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs773981549; called by muse, mutect2, varscan2
- CREB3L2 | c.880G>T p.A294S | Missense Mutation (SNP) | VAF 58/329 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.533); catalogued as rs1352193617; called by muse, mutect2, varscan2
- CRIP3 | c.382G>T p.G128W | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99240559; called by muse, mutect2, varscan2
- CRYBB2 | c.436G>T p.V146L | Missense Mutation (SNP) | VAF 112/399 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as CM111886; called by muse, mutect2, varscan2
- CSMD1 | c.8830C>A p.R2944S (on ENST00000520002; = p.R2943S on NM_033225.6) | Missense Mutation (SNP) | VAF 99/298 reads (33%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.928); catalogued as COSV59318142; called by muse, varscan2
- CSMD3 | c.7777C>A p.R2593S (on ENST00000297405 / NM_001363185.1; = p.R2489S on NM_052900.3) | Missense Mutation (SNP) | VAF 53/254 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV52164475, COSV52212859; called by muse, mutect2, varscan2
- CSMD3 | c.1987A>T p.S663C (on ENST00000297405 / NM_001363185.1; = p.S559C on NM_052900.3) | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV52307766; called by muse, mutect2, varscan2
- CTH | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 52/355 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61007360, COSV61007706; called by muse, mutect2, varscan2
- CYLC2 | c.470C>A p.A157E | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV66337187; called by muse, mutect2, varscan2
- DACH1 | c.1761C>G p.D587E (on ENST00000619232 / NM_001366712.1; = p.D333E on NM_004392.6) | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.028); catalogued as COSV57520064; called by muse, mutect2, varscan2
- DACH1 | c.1427C>A p.P476Q (on ENST00000619232 / NM_001366712.1; = p.P424Q on NM_080759.6) | Missense Mutation (SNP) | VAF 44/106 reads (42%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.885); catalogued as COSV57518177; called by muse, mutect2, varscan2
- DACH2 | c.1303G>T p.G435W | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV64167402; called by muse, mutect2, varscan2
- DCLK3 | c.157C>G p.R53G | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV69362100, COSV69362635; called by muse, mutect2, varscan2
- DDX31 | c.2419G>T p.A807S | Missense Mutation (SNP) | VAF 76/603 reads (13%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.019); catalogued as rs751295139, COSV99707404; called by muse, mutect2, varscan2
- DDX41 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 132/462 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs11555633; called by muse, mutect2, varscan2
- DDX53 | c.1319C>T p.T440I | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs769462069; called by muse, mutect2, varscan2
- DECR1 | c.999A>T p.K333N | Missense Mutation (SNP) | VAF 53/176 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs15094; called by muse, mutect2, varscan2
- DENND2A | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 28/162 reads (17%) | catalogued as COSV52059599; called by muse, mutect2, varscan2
- DGKI | c.2600C>A p.P867Q | Missense Mutation (SNP) | VAF 126/303 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV55938146; called by muse, mutect2
- DGKK | c.1665G>C p.W555C | Missense Mutation (SNP) | VAF 51/194 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65708764; called by muse, mutect2, varscan2
- DIP2B | c.635G>T p.R212L | Missense Mutation (SNP) | VAF 38/159 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as COSV56583305; called by muse, mutect2
- DLG2 | c.1762G>A p.G588R | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV54687195; called by muse, mutect2, varscan2
- DLX6 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 81/211 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); catalogued as COSV50295543; called by muse, mutect2, varscan2
- DMD | c.1292G>T p.W431L | Missense Mutation (SNP) | VAF 163/243 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM070909; called by muse, mutect2, varscan2
- DNAH3 | c.10735C>G p.Q3579E | Missense Mutation (SNP) | VAF 67/390 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs757844714; called by muse, mutect2, varscan2
- DNAH9 | c.6134G>T p.R2045L | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52358159; called by muse, mutect2, varscan2
- DNAI2 | c.440C>A p.P147H | Missense Mutation (SNP) | VAF 131/469 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV100209548; called by muse, mutect2, varscan2
- DNAJB13 | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 123/299 reads (41%) | catalogued as rs1246467052; called by muse, mutect2, varscan2
- DNAJC1 | c.1256G>T p.G419V | Missense Mutation (SNP) | VAF 144/499 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV65409674; called by muse, mutect2, varscan2
- DNMBP | c.3523G>T p.A1175S | Missense Mutation (SNP) | VAF 70/405 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100143811; called by muse, mutect2, varscan2
- DOCK10 | c.2004C>A p.Y668* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV51425081; called by muse, mutect2, varscan2
- DOCK4 | c.2245G>A p.E749K | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs751288054; called by muse, mutect2, varscan2
- DPP6 | c.51G>T p.M17I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.38); catalogued as rs781150778; ClinVar: uncertain significance; called by muse, varscan2
- DPP6 | c.1988G>T p.R663L (on ENST00000377770 / NM_001364500.2; = p.R601L on NM_001936.5) | Missense Mutation (SNP) | VAF 106/230 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59643903; called by muse, mutect2, varscan2
- DPY19L2 | c.2186C>A p.P729H | Missense Mutation (SNP) | VAF 105/388 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as COSV100192734; called by muse, mutect2, varscan2
- DPY19L2 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.145); catalogued as rs1220779082, COSV100116657; called by muse, mutect2, varscan2
- DUOXA2 | c.40C>A p.P14T | Missense Mutation (SNP) | VAF 200/699 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs1021093996; called by muse, mutect2, varscan2
- DVL1 | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 87/553 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs944936291; called by muse, mutect2, varscan2
- DYSF | c.2690C>T p.T897M | Missense Mutation (SNP) | VAF 135/477 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.185); catalogued as rs769739410, COSV99249939; ClinVar: uncertain significance; called by muse, varscan2
- EGR4 | c.853G>A p.V285I (on ENST00000545030; = p.V182I on NM_001965.4) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs564426644; called by muse, mutect2, varscan2
- ELAVL4 | c.478A>G p.T160A | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.839); catalogued as COSV100836952; called by muse, mutect2, varscan2
- ELOVL7 | c.473G>A p.W158* | Nonsense Mutation (SNP) | VAF 108/321 reads (34%) | catalogued as rs768134267; called by muse, mutect2, varscan2
- EMILIN1 | c.1816C>A p.L606M | Missense Mutation (SNP) | VAF 117/573 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV53155866, COSV53155993; called by muse, mutect2, varscan2
- EOLA2 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as COSV100778095; called by mutect2, varscan2
- EPB41L5 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 23/136 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55348550; called by muse, mutect2, varscan2
- EPHA6 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1374125907, COSV101063111, COSV67585991; called by muse, mutect2, varscan2
- EPS8L1 | c.1471G>T p.A491S (on ENST00000201647 / NM_133180.3; = p.A364S on NM_017729.3) | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV52379833; called by muse, mutect2, varscan2
- EPYC | c.722A>G p.H241R | Missense Mutation (SNP) | VAF 74/239 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.288); catalogued as rs758118677; called by muse, mutect2, varscan2
- ESCO1 | c.1200C>G p.N400K | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs757551403; called by muse, mutect2, varscan2
- ESR2 | c.1525G>A p.G509R | Missense Mutation (SNP) | VAF 73/238 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV50833200; called by muse, mutect2, varscan2
- ESRP1 | c.986G>T p.R329L | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344070630, COSV64412266; called by muse, mutect2, varscan2
- ESRRB | c.676G>T p.A226S | Missense Mutation (SNP) | VAF 106/315 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV99835126; called by muse, mutect2, varscan2
- EXT2 | c.5G>T p.C2F (on ENST00000343631; = p.C35F on NM_000401.3) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.035); catalogued as rs1565196088; called by muse, mutect2, varscan2
- F11 | c.1334A>T p.Y445F | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as CM995127; called by muse, mutect2, varscan2
- F8 | c.4863C>A p.N1621K | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.03); catalogued as COSV64273136; called by muse, mutect2, varscan2
- FAM102A | c.988G>T p.V330L (on ENST00000373095 / NM_001035254.3; = p.V188L on NM_203305.2) | Missense Mutation (SNP) | VAF 114/286 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100305597; called by muse, mutect2, varscan2
- FAM104A | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 78/256 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.754); catalogued as rs749798858; called by muse, mutect2, varscan2
- FAM170A | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV58925088, COSV58925339; called by muse, mutect2, varscan2
- FAM227B | c.1007C>A p.S336* | Nonsense Mutation (SNP) | VAF 28/107 reads (26%) | catalogued as COSV100174813; called by muse, mutect2, varscan2
- FAM71F2 | c.229G>C p.V77L | Missense Mutation (SNP) | VAF 241/731 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV66352411; called by muse, mutect2
- FAM83B | c.2786C>A p.T929N | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.034); catalogued as COSV60920191; called by muse, mutect2, varscan2
- FAT3 | c.9713G>C p.R3238T | Missense Mutation (SNP) | VAF 139/417 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as COSV53132527; called by muse, mutect2, varscan2
- FBLN7 | c.1088C>A p.P363H | Missense Mutation (SNP) | VAF 91/369 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99735000; called by muse, mutect2, varscan2
- FBXO38 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV57030219; called by muse, mutect2, varscan2
- FBXO38 | c.1859G>T p.R620L | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.013); catalogued as COSV57026710; called by muse, mutect2, varscan2
- FBXO40 | c.301C>A p.R101S | Missense Mutation (SNP) | VAF 67/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57522667; called by muse, mutect2, varscan2
- FBXO40 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 43/180 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57524889; called by muse, mutect2, varscan2
- FBXW7 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.069); catalogued as COSV99898738, COSV99900887; called by muse, mutect2, varscan2
- FBXW8 | c.563C>T p.P188L (on ENST00000309909; = p.P226L on NM_012174.1) | Missense Mutation (SNP) | VAF 94/272 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.843); catalogued as rs1175677041, COSV59302564, COSV99997913; called by muse, mutect2, varscan2
- FCHO1 | c.829C>A p.Q277K | Missense Mutation (SNP) | VAF 130/274 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as rs749294013; called by muse, mutect2, varscan2
- FER1L6 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 90/366 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205212; called by muse, mutect2, varscan2
- FGB | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV100122258; called by muse, mutect2, varscan2
- FGFBP3 | c.35C>T p.P12L | Missense Mutation (SNP) | VAF 101/556 reads (18%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs200280119; called by muse, mutect2, varscan2
- FLG | c.8498G>A p.G2833E | Missense Mutation (SNP) | VAF 243/1213 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as rs1401517481, COSV64246918; called by muse, mutect2, varscan2
- FLG | c.6181G>C p.A2061P | Missense Mutation (SNP) | VAF 315/923 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.441); catalogued as rs1245044789; called by muse, mutect2, varscan2
- FLG | c.5650C>A p.R1884S | Missense Mutation (SNP) | VAF 322/925 reads (35%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.719); catalogued as COSV64242050; called by muse, mutect2, varscan2
- FLG2 | c.5684C>A p.T1895K | Missense Mutation (SNP) | VAF 129/508 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs1305913928; called by muse, mutect2, varscan2
- FMN2 | c.3413C>A p.A1138E | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs199570117; called by muse, varscan2
- FMR1 | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 58/214 reads (27%) | catalogued as COSV54424364; called by muse, mutect2, varscan2
- FRG2 | c.287G>T p.R96M | Missense Mutation (SNP) | VAF 44/394 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV66460548; called by muse, varscan2
- FSCB | c.343G>T p.V115L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV61217816; called by muse, mutect2, varscan2
- FSCB | c.59C>G p.P20R | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs572138282; called by muse, mutect2, varscan2
- FSCN3 | c.1274G>T p.G425V | Missense Mutation (SNP) | VAF 61/153 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs751230329; called by muse, mutect2, varscan2
- FUT6 | c.207G>T p.W69C | Missense Mutation (SNP) | VAF 176/312 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747596068; called by muse, mutect2, varscan2
- FUT8 | c.79G>T p.G27C | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.998); catalogued as COSV61289334; called by muse, mutect2, varscan2
- GABRB3 | c.88G>C p.G30R | Missense Mutation (SNP) | VAF 81/331 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV59483112; called by muse, mutect2, varscan2
- GABRR1 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 76/267 reads (28%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.911); catalogued as rs1562298617, COSV101034070, COSV65619209; called by muse, mutect2, varscan2
- GAGE1 | c.332-1G>T p.X111_splice | Splice Site (SNP) | VAF 40/107 reads (37%) | catalogued as rs373465046; called by muse, mutect2, varscan2
- GALC | c.1671-2A>T p.X557_splice | Splice Site (SNP) | VAF 25/111 reads (23%) | catalogued as CS162996, COSV54331432; called by muse, mutect2, varscan2
- GAS2L2 | c.1753G>A p.G585R | Missense Mutation (SNP) | VAF 104/366 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs782648695; called by muse, mutect2, varscan2
- GATA4 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.494); catalogued as rs1243318122; called by muse, mutect2, varscan2
- GBX1 | c.1062C>A p.H354Q | Missense Mutation (SNP) | VAF 101/208 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs1335748337; called by muse, mutect2, varscan2
- GCN1 | c.1507G>C p.D503H | Missense Mutation (SNP) | VAF 108/279 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as rs758642782; called by muse, mutect2, varscan2
- GEMIN6 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs772095779; called by muse, mutect2, varscan2
- GIMAP8 | c.826G>C p.G276R | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV56233018; called by muse, mutect2, varscan2
- GJA8 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 177/504 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.468); catalogued as COSV99569263, COSV99569526; called by muse, mutect2, varscan2
- GK2 | c.611G>A p.R204K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1218862963; called by muse, mutect2, varscan2
- GK2 | c.300G>A p.W100* | Nonsense Mutation (SNP) | VAF 19/159 reads (12%) | catalogued as COSV62627973; called by muse, mutect2, varscan2
- GK5 | c.892G>T p.G298W | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67486744; called by muse, mutect2, varscan2
- GLIS2 | c.895G>T p.G299C | Missense Mutation (SNP) | VAF 289/798 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs192213553; called by muse, mutect2, varscan2
- GP2 | c.1069C>A p.L357I (on ENST00000381362 / NM_001007240.3; = p.L354I on NM_001502.4) | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56894935; called by muse, mutect2, varscan2
- GRID1 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60037930; called by muse, mutect2, varscan2
- GRIN3A | c.1415C>A p.P472H | Missense Mutation (SNP) | VAF 71/161 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100701639; called by muse, mutect2, varscan2
- GRK6 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 104/347 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs753249774; called by muse, mutect2, varscan2
- GRM1 | c.823C>A p.R275S | Missense Mutation (SNP) | VAF 159/586 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.506); catalogued as rs766567009, COSV51198697; called by muse, mutect2, varscan2
- H2AC12 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.038); catalogued as rs778170423, COSV63617316; called by muse, mutect2, varscan2
- H3C4 | c.342C>A p.H114Q | Missense Mutation (SNP) | VAF 176/580 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.623); catalogued as COSV100587268; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 124/368 reads (34%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HCAR3 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 199/614 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs977516577, COSV63673677; called by muse, mutect2, varscan2
- HCN1 | c.2540C>A p.S847* | Nonsense Mutation (SNP) | VAF 64/191 reads (34%) | catalogued as COSV100300556; called by muse, varscan2
- HCN1 | c.1496del p.G499Efs*32 | Frame Shift Del (DEL) | VAF 113/462 reads (24%) | catalogued as COSV57508108; called by mutect2, pindel, varscan2
- HEATR5B | c.6167C>T p.P2056L | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV51852866; called by muse, mutect2, varscan2
- HERC2 | c.6623C>T p.A2208V | Missense Mutation (SNP) | VAF 85/702 reads (12%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV55353809; called by muse, mutect2, varscan2
- HERC6 | c.678G>T p.K226N | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as rs777148021; called by muse, mutect2, varscan2
- HIVEP3 | c.4756G>T p.G1586C | Missense Mutation (SNP) | VAF 80/250 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV56020503; called by muse, mutect2
- HMX2 | c.145G>T p.V49L | Missense Mutation (SNP) | VAF 70/365 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs927360192, COSV60592792; called by muse, mutect2, varscan2
- HPSE | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs766025621; called by muse, mutect2, varscan2
- HS3ST4 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.03); catalogued as rs547472104; called by muse, mutect2
- HS3ST4 | c.984G>T p.W328C | Missense Mutation (SNP) | VAF 52/310 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100500719, COSV58802705; called by muse, mutect2, varscan2
- HTRA3 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 108/289 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56469510; called by muse, mutect2, varscan2
- HUS1B | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 71/233 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.033); catalogued as rs776185878, COSV57867908; called by muse, mutect2, varscan2
- HYDIN | c.6607G>T p.G2203W | Missense Mutation (SNP) | VAF 41/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59272155; called by muse, mutect2, varscan2
- IFT88 | c.485G>A p.C162Y (on ENST00000319980 / NM_001318493.2; = p.C153Y on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs779962847; called by muse, mutect2, varscan2
- IGFBP1 | c.455G>T p.W152L | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV51875303; called by muse, mutect2, varscan2
- IGFL3 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 101/318 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.142); catalogued as COSV58243312; called by muse, mutect2, varscan2
- IGHV3-13 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 51/268 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.579); catalogued as rs111986975; called by muse, mutect2, varscan2
- IGLV11-55 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.487); catalogued as rs1568988437; called by muse, mutect2, varscan2
- IGLV2-8 | c.253G>T p.G85C | Missense Mutation (SNP) | VAF 278/808 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs757487920; called by muse, mutect2, varscan2
- IL1RAPL1 | c.1750C>A p.L584M | Missense Mutation (SNP) | VAF 66/294 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56254561; called by muse, varscan2
- IL1RAPL1 | c.1781C>G p.A594G | Missense Mutation (SNP) | VAF 119/236 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.194); catalogued as COSV100148523; called by muse, varscan2
- IL1RL2 | c.1190A>G p.Q397R | Missense Mutation (SNP) | VAF 63/226 reads (28%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.856); catalogued as rs1285132837; called by muse, mutect2, varscan2
- INPP4B | c.619G>T p.A207S | Missense Mutation (SNP) | VAF 38/149 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV53734762; called by muse, varscan2
- IPO8 | c.2980G>T p.V994L | Missense Mutation (SNP) | VAF 72/375 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as rs772601072; called by muse, mutect2, varscan2
- IPO8 | c.2979G>T p.E993D | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.02); catalogued as rs1180971035; called by muse, mutect2, varscan2
- IRS4 | c.3079C>A p.P1027T | Missense Mutation (SNP) | VAF 58/198 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as COSV100929641; called by muse, mutect2, varscan2
- IRX3 | c.47C>T p.P16L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as rs1189396482; called by muse, mutect2
- IRX4 | c.552G>T p.M184I | Missense Mutation (SNP) | VAF 134/696 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99182914; called by muse, mutect2, varscan2
- ITGAD | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1303837397; called by muse, mutect2, varscan2
- ITGB8 | c.505G>T p.V169F | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV56004933; called by muse, mutect2, varscan2
- KALRN | c.42G>C p.W14C | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious, low confidence (0.04); catalogued as rs1188004725; called by muse, mutect2, varscan2
- KANSL1 | c.1856G>A p.R619Q | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1424923651, COSV99294919; called by muse, mutect2, varscan2
- KCMF1 | c.199G>T p.G67W | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101301220; called by muse, mutect2, varscan2
- KCNH3 | c.1040C>G p.P347R | Missense Mutation (SNP) | VAF 306/800 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV57790879; called by muse, varscan2
- KCNH6 | c.821C>A p.T274K | Missense Mutation (SNP) | VAF 173/574 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.234); catalogued as COSV59002852; called by muse, mutect2, varscan2
- KCNJ4 | c.1315T>A p.Y439N | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV57856463; called by muse, mutect2, varscan2
- KCNK10 | c.1132C>G p.R378G | Missense Mutation (SNP) | VAF 99/259 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV100067993; called by muse, mutect2, varscan2
- KCNK15 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 73/245 reads (30%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.031); catalogued as rs1445884163; called by muse, mutect2, varscan2
- KHDC4 | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64165998; called by muse, mutect2, varscan2
- KIRREL3 | c.2146C>A p.L716I | Missense Mutation (SNP) | VAF 196/577 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.042); catalogued as COSV69385269; called by muse, mutect2, varscan2
- KLHDC7A | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 136/275 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.779); catalogued as rs1452627019; called by muse, mutect2, varscan2
- KLHL1 | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 34/74 reads (46%) | catalogued as COSV100917321; called by muse, mutect2, varscan2
- KLHL13 | c.1105T>A p.W369R | Missense Mutation (SNP) | VAF 40/205 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53251230; called by muse, mutect2, varscan2
- KLHL15 | c.1677del p.I560Sfs*67 | Frame Shift Del (DEL) | VAF 42/192 reads (22%) | catalogued as COSV60141258; called by mutect2, pindel, varscan2
- KLHL41 | c.1454G>T p.R485L | Missense Mutation (SNP) | VAF 31/150 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV52929456; called by muse, mutect2, varscan2
- KLK15 | c.481+4C>G | Splice Region (SNP) | VAF 19/69 reads (28%) | catalogued as COSV56827656; called by muse, mutect2, varscan2
- KLK15 | c.368G>T p.R123L | Missense Mutation (SNP) | VAF 95/248 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV56826427; called by muse, mutect2, varscan2
- KLRG2 | c.105del p.A36Rfs*91 | Frame Shift Del (DEL) | VAF 106/533 reads (20%) | catalogued as COSV61800408; called by pindel, varscan2
- L3MBTL3 | c.698G>C p.C233S | Missense Mutation (SNP) | VAF 134/430 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs906721951, COSV62386579; called by muse, mutect2, varscan2
- LAMC3 | c.3770G>T p.G1257V | Missense Mutation (SNP) | VAF 247/484 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV62655734; called by muse, mutect2, varscan2
- LCE6A | c.165G>T p.R55S | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.26); catalogued as COSV101440604; called by muse, mutect2, varscan2
- LGR5 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 61/222 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.922); catalogued as rs752965639; called by mutect2, varscan2
- LHX3 | c.928C>A p.R310S (on ENST00000371748 / NM_178138.6; = p.R315S on NM_014564.5) | Missense Mutation (SNP) | VAF 73/143 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as rs548961945; called by muse, mutect2, varscan2
- LHX8 | c.391A>T p.R131W | Missense Mutation (SNP) | VAF 110/287 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99634596; called by muse, mutect2, varscan2
- LILRB1 | c.1393C>A p.P465T (on ENST00000427581; = p.P429T on NM_006669.6) | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs771021905; called by muse, mutect2, varscan2
- LINGO2 | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 78/141 reads (55%) | catalogued as COSV58059759; called by muse, mutect2, varscan2
- LIPI | c.110A>G p.D37G | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1207796725; called by muse, mutect2, varscan2
- LMBR1L | c.1168A>T p.T390S | Missense Mutation (SNP) | VAF 81/329 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.412); catalogued as rs1162869875; called by muse, mutect2, varscan2
- LOXHD1 | c.890C>T p.T297M | Missense Mutation (SNP) | VAF 72/211 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs748673610; called by muse, mutect2, varscan2
- LPA | c.4337C>T p.P1446L | Missense Mutation (SNP) | VAF 96/369 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100307522; called by muse, mutect2, varscan2
- LRFN2 | c.1846G>T p.A616S | Missense Mutation (SNP) | VAF 76/263 reads (29%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as rs1345589229, COSV57833079; called by muse, mutect2, varscan2
- LRIT1 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 104/642 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.143); catalogued as COSV100928200; called by muse, mutect2, varscan2
- LRIT1 | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 27/185 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs770262471; called by muse, mutect2
- LRP2 | c.4093G>T p.V1365F | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as COSV99786940; called by muse, mutect2, varscan2
- LRRC4C | c.527G>T p.R176L | Missense Mutation (SNP) | VAF 49/163 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.257); catalogued as COSV53419153; called by muse, mutect2, varscan2
- LRRC7 | c.2107+1del | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | catalogued as COSV50494664; called by mutect2, pindel, varscan2
- LRRK1 | c.1754G>T p.R585L | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV52621830; called by muse, mutect2, varscan2
- LRRN2 | c.1882C>A p.R628S | Missense Mutation (SNP) | VAF 128/469 reads (27%) | SIFT tolerated (0.65); PolyPhen benign (0.06); catalogued as rs769164284; called by muse, mutect2, varscan2
- LRRTM4 | c.1048G>T p.V350F | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV69139301; called by muse, varscan2
- LTBP1 | c.1210C>A p.H404N (on ENST00000404816 / NM_206943.4; = p.H78N on NM_000627.4) | Missense Mutation (SNP) | VAF 35/181 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV63184526; called by muse, mutect2, varscan2
- LTBP1 | c.3646G>T p.G1216W (on ENST00000404816 / NM_206943.4; = p.G890W on NM_000627.4) | Missense Mutation (SNP) | VAF 37/215 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55379956; called by muse, mutect2, varscan2
- LY6L | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 42/122 reads (34%) | catalogued as COSV73805936; called by muse, mutect2, varscan2
- LYST | c.10912G>C p.G3638R | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67714502; called by muse, mutect2, varscan2
- MAB21L1 | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.615); catalogued as rs373870848; called by muse, mutect2, varscan2
- MAGEA10 | c.1055C>G p.T352S | Missense Mutation (SNP) | VAF 56/171 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1320897948; called by muse, mutect2, varscan2
- MAGEB4 | c.55C>A p.R19S | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV64397289; called by muse, mutect2
- MAGEC1 | c.2065C>A p.L689M | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.062); catalogued as rs762488148; called by muse, mutect2, varscan2
- MAGEL2 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1295086151; called by muse, mutect2, varscan2
- MAP3K19 | c.2048C>A p.T683K | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200164509; called by muse, mutect2, varscan2
- MAP3K5 | c.3986G>T p.R1329L | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.044); catalogued as COSV62891328; called by muse, mutect2, varscan2
- MCTP1 | c.1173+1G>T p.X391_splice | Splice Site (SNP) | VAF 15/58 reads (26%) | catalogued as rs760063047; called by muse, mutect2, varscan2
- MDM2 | c.46A>T p.T16S | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV99254558; called by muse, mutect2, varscan2
- MEFV | c.239G>C p.R80P | Missense Mutation (SNP) | VAF 121/633 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV54824451; called by muse, mutect2, varscan2
- MEGF10 | c.655G>T p.A219S | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.951); catalogued as COSV57258218; called by muse, mutect2
- MEPCE | c.974G>T p.R325M | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV52768817; called by muse, mutect2, varscan2
- METRNL | c.764G>A p.R255K | Missense Mutation (SNP) | VAF 37/212 reads (17%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV60761641; called by muse, mutect2, varscan2
- MFSD6 | c.328C>A p.R110S | Missense Mutation (SNP) | VAF 56/184 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752956733; called by muse, mutect2, varscan2
- MGA | c.872G>A p.R291Q | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.637); catalogued as rs1246317040, COSV99582033; called by muse, mutect2, varscan2
- MID2 | c.1864G>T p.A622S | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV53308439, COSV53315500; called by muse, mutect2, varscan2
- MIGA1 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.468); catalogued as rs755719015; called by muse, mutect2, varscan2
- MMP16 | c.329G>T p.S110I | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs867643912, COSV54160622; called by muse, mutect2, varscan2
- MMP17 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 59/160 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs759602929, COSV62181642; called by muse, mutect2, varscan2
- MN1 | c.3087C>A p.D1029E | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); catalogued as COSV56557674; called by muse, mutect2, varscan2
- MOSPD3 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs775947023, COSV56158849; called by muse, mutect2, varscan2
- MOSPD3 | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 148/383 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs778222272; called by muse, mutect2, varscan2
- MRGPRF | c.66C>A p.S22R | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as rs376550077; called by muse, mutect2, varscan2
- MRGPRX3 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV66933255; called by muse, mutect2, varscan2
- MRPS5 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 44/170 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55533073; called by muse, mutect2, varscan2
- MS4A6E | c.220A>T p.N74Y | Missense Mutation (SNP) | VAF 114/409 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.383); catalogued as rs1490664728; called by muse, mutect2, varscan2
- MSH3 | c.2656-1G>T p.X886_splice | Splice Site (SNP) | VAF 44/156 reads (28%) | catalogued as COSV99432231; called by muse, mutect2, varscan2
- MSX1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 90/202 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV101235698; called by muse, varscan2
- MTUS2 | c.2431A>T p.S811C | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as COSV70921730; called by muse, mutect2, varscan2
- MTUS2 | c.3307C>T p.R1103W (on ENST00000612955 / NM_001366650.1; = p.R82W on NM_015233.6) | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs764707896; called by muse, mutect2, varscan2
- MUC16 | c.30166C>A p.P10056T | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.044); catalogued as COSV101202087; called by muse, mutect2, varscan2
- MUC19 | c.893G>T p.G298V | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.98); catalogued as rs1384970154; called by muse, mutect2, varscan2
- MUC4 | c.7255G>C p.V2419L | Missense Mutation (SNP) | VAF 210/1465 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.101); catalogued as rs1220113340; called by muse, mutect2, varscan2
- MXRA5 | c.7195C>A p.Q2399K | Missense Mutation (SNP) | VAF 131/294 reads (45%) | SIFT tolerated (0.75); PolyPhen benign (0.173); catalogued as COSV54239498; called by muse, mutect2, varscan2
- MYH13 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 92/305 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV52820887; called by muse, mutect2, varscan2
- MYH4 | c.2014del p.H672Tfs*26 | Frame Shift Del (DEL) | VAF 47/261 reads (18%) | catalogued as rs1228204503; called by mutect2, pindel, varscan2
- MYH9 | c.3452C>T p.T1151M | Missense Mutation (SNP) | VAF 146/384 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs375081687; called by muse, varscan2
- MYO15A | c.7402G>C p.E2468Q | Missense Mutation (SNP) | VAF 270/967 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.135); catalogued as rs1412467176, COSV99232507; called by muse, mutect2, varscan2
- MYO7B | c.2524C>A p.L842M | Missense Mutation (SNP) | VAF 130/499 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.764); catalogued as COSV67344241; called by muse, mutect2, varscan2
- MYO7B | c.2664del p.E889Rfs*37 | Frame Shift Del (DEL) | VAF 41/144 reads (28%) | catalogued as COSV67348279; called by mutect2, pindel, varscan2
- MYOD1 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 26/147 reads (18%) | catalogued as COSV51452810, COSV51454705; called by muse, mutect2, varscan2
- NAT16 | c.326C>T p.S109L | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs369492361; called by muse, mutect2, varscan2
- NAT8 | c.82C>A p.H28N | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as COSV55542950; called by muse, mutect2, varscan2
- NAV3 | c.4345A>G p.T1449A | Missense Mutation (SNP) | VAF 84/274 reads (31%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.993); catalogued as rs1202248307, COSV99031035; called by muse, mutect2, varscan2
- NELL2 | c.1826G>C p.G609A | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.368); catalogued as COSV61569557; called by muse, mutect2, varscan2
- NGEF | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1300856901, COSV50914726, COSV50943982; called by muse, varscan2
- NID2 | c.2006T>A p.L669Q | Missense Mutation (SNP) | VAF 73/166 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV53498299; called by muse, mutect2, varscan2
- NLRP1 | c.2737G>T p.D913Y | Missense Mutation (SNP) | VAF 55/181 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.379); catalogued as rs1419431079; called by muse, mutect2, varscan2
- NLRP12 | c.1512C>G p.I504M | Missense Mutation (SNP) | VAF 281/1131 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.028); catalogued as COSV60755059; called by muse, mutect2, varscan2
- NLRP13 | c.1550A>T p.Y517F | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.054); catalogued as COSV100738079; called by muse, mutect2, varscan2
- NLRP2 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 158/397 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV54758420; called by muse, varscan2
- NLRP4 | c.2741C>A p.A914E | Missense Mutation (SNP) | VAF 92/220 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs769137352, COSV56707773, COSV56707879; called by muse, mutect2, varscan2
- NOC2L | c.1716G>T p.Q572H | Missense Mutation (SNP) | VAF 122/338 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58988045; called by muse, mutect2, varscan2
- NOP56 | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 101/366 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61388773; called by muse, mutect2, varscan2
- NPAP1 | c.223C>A p.P75T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.412); catalogued as COSV61511600; called by muse, mutect2, varscan2
- NPHS1 | c.191G>A p.W64* | Nonsense Mutation (SNP) | VAF 337/881 reads (38%) | catalogued as CM990949; called by muse, mutect2, varscan2
- NPPC | c.27C>A p.C9* | Nonsense Mutation (SNP) | VAF 14/42 reads (33%) | catalogued as COSV54945647; called by muse, mutect2, varscan2
- NR2E1 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 148/592 reads (25%) | SIFT tolerated (0.7); PolyPhen benign (0.133); catalogued as COSV64562255; called by muse, mutect2, varscan2
- NR3C2 | c.740G>T p.R247M | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV60985062; called by muse, mutect2, varscan2
- NRG1 | c.1284G>T p.M428I (on ENST00000405005 / NM_013964.5; = p.M433I on NM_013956.5) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV55176044; called by muse, mutect2, varscan2
- NRG3 | c.1865T>A p.I622N (on ENST00000404547 / NM_001370084.1; = p.I598N on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 54/277 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV64579875; called by muse, mutect2, varscan2
- NRK | c.3505G>T p.A1169S | Missense Mutation (SNP) | VAF 46/143 reads (32%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs377439740; called by muse, mutect2, varscan2
- NRXN1 | c.4363G>T p.E1455* | Nonsense Mutation (SNP) | VAF 37/221 reads (17%) | catalogued as COSV60520265; called by muse, mutect2, varscan2
- NRXN2 | c.1084G>T p.E362* | Nonsense Mutation (SNP) | VAF 227/743 reads (31%) | catalogued as COSV55456916, COSV99634967; called by muse, mutect2, varscan2
- NSUN6 | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 52/186 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66031808; called by muse, mutect2, varscan2
- NUDT6 | c.80G>T p.R27L | Missense Mutation (SNP) | VAF 178/466 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs772875454; called by muse, mutect2, varscan2
- OBSL1 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 109/323 reads (34%) | catalogued as COSV54714385, COSV54717312; called by muse, mutect2, varscan2
- OCA2 | c.119G>T p.R40L | Missense Mutation (SNP) | VAF 221/857 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV62349210; called by muse, mutect2, varscan2
- OGFR | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 71/268 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51697898; called by muse, mutect2, varscan2
- OGT | c.2293G>A p.A765T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs765863058; called by muse, mutect2, varscan2
- OPRM1 | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 108/448 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.614); catalogued as rs777099271, COSV100002380; called by muse, mutect2, varscan2
- OPRM1 | c.1117A>G p.R373G | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.71); catalogued as rs1355646642; called by muse, mutect2, varscan2
- OR10D3 | c.572A>T p.D191V | Missense Mutation (SNP) | VAF 62/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1233714948; called by muse, mutect2, varscan2
- OR10G7 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 72/224 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1565596559, COSV57867392; called by muse, varscan2
- OR10J1 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 114/425 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs772118508, COSV71128835; called by muse, mutect2, varscan2
- OR10Q1 | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 103/330 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV57470793; called by muse, varscan2
- OR10Q1 | c.437C>A p.T146K | Missense Mutation (SNP) | VAF 108/308 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV57470145; called by muse, varscan2
- OR1D5 | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 145/727 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs577309070; called by muse, mutect2, varscan2
- OR2A1 | c.269C>A p.P90H | Missense Mutation (SNP) | VAF 327/1667 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as COSV101283348; called by muse, mutect2, varscan2
- OR2T12 | c.868G>T p.V290L | Missense Mutation (SNP) | VAF 53/291 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs756113026; called by muse, mutect2, varscan2
- OR2T27 | c.538G>T p.E180* | Nonsense Mutation (SNP) | VAF 112/400 reads (28%) | catalogued as COSV100788381; called by muse, mutect2, varscan2
- OR51E2 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 54/389 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756220257, COSV67807507; called by muse, mutect2, varscan2
- OR52D1 | c.425C>G p.A142G | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs780502302, COSV100495159; called by muse, mutect2, varscan2
- OR52E8 | c.252C>G p.I84M | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs755795212; called by muse, mutect2, varscan2
- OR52J3 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs1040215387; called by muse, mutect2, varscan2
- OR5B12 | c.832A>G p.I278V | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.006); catalogued as COSV56905083; called by muse, mutect2, varscan2
- OR5B12 | c.503G>T p.R168I | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.144); catalogued as COSV100222579, COSV56904724; called by muse, mutect2, varscan2
- OR5D13 | c.584A>T p.Y195F | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.049); catalogued as COSV62333067, COSV62333880; called by muse, mutect2, varscan2
- OR5H2 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV62351041; called by muse, mutect2, varscan2
- OR5K4 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 74/241 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100721331; called by muse, mutect2, varscan2
- OR5R1 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 56/209 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56571664; called by muse, mutect2, varscan2
- OR6B3 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 58/293 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs1250544037, COSV100097298; called by muse, mutect2, varscan2
- OR8H2 | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 70/215 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57943721; called by muse, varscan2
- OR9Q2 | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 86/288 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV61112009; called by muse, mutect2, varscan2
- OTOF | c.1480C>A p.R494S | Missense Mutation (SNP) | VAF 56/257 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55512507, COSV55516456; called by muse, mutect2, varscan2
- OTOG | c.4132G>A p.A1378T | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs976267798; called by muse, mutect2, varscan2
- OVCH1 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV58961568; called by muse, mutect2, varscan2
- OXER1 | c.158C>A p.S53Y | Missense Mutation (SNP) | VAF 119/545 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.038); catalogued as COSV54310621; called by muse, mutect2, varscan2
- P4HB | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.688); catalogued as rs149469078; called by muse, mutect2, varscan2
- PADI6 | c.1408del p.E470Sfs*7 | Frame Shift Del (DEL) | VAF 102/311 reads (33%) | catalogued as COSV100640014; called by mutect2, pindel, varscan2
- PASD1 | c.1633G>T p.E545* | Nonsense Mutation (SNP) | VAF 80/275 reads (29%) | catalogued as COSV64857672; called by muse, mutect2
- PCDHA10 | c.2351G>C p.G784A | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV100252645; called by muse, mutect2, varscan2
- PCDHA11 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 108/636 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV56505342; called by muse, mutect2, varscan2
- PCDHA3 | c.1192G>T p.V398L | Missense Mutation (SNP) | VAF 63/377 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.213); catalogued as COSV63542430; called by muse, mutect2, varscan2
- PCDHA3 | c.1449C>A p.D483E | Missense Mutation (SNP) | VAF 137/986 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1230044523, COSV63542712; called by muse, mutect2, varscan2
- PCDHA8 | c.2066C>A p.P689Q | Missense Mutation (SNP) | VAF 93/518 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.018); catalogued as rs782229636, COSV65323709; called by muse, mutect2, varscan2
- PCDHB2 | c.1814C>A p.S605* | Nonsense Mutation (SNP) | VAF 161/658 reads (24%) | catalogued as COSV99164107; called by muse, mutect2, varscan2
- PCDHB3 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 67/169 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs202034696; called by muse, mutect2, varscan2
- PCDHB4 | c.2217C>A p.S739R | Missense Mutation (SNP) | VAF 88/546 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.272); catalogued as COSV52020200; called by muse, varscan2
- PCDHB6 | c.2186C>G p.P729R | Missense Mutation (SNP) | VAF 139/352 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50699349; called by muse, mutect2, varscan2
- PCDHGA11 | c.1909G>T p.D637Y | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV53915470, COSV53917862; called by muse, mutect2, varscan2
- PCDHGA4 | c.2205C>A p.F735L | Missense Mutation (SNP) | VAF 35/235 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV53952655; called by muse, mutect2, varscan2
- PCDHGB3 | c.1002G>T p.Q334H | Missense Mutation (SNP) | VAF 67/176 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.055); catalogued as COSV54003448, COSV99538013; called by muse, mutect2, varscan2
- PCIF1 | c.316G>T p.A106S | Missense Mutation (SNP) | VAF 52/215 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100976006; called by muse, mutect2, varscan2
- PDE6C | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 49/288 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV65114990; called by muse, mutect2, varscan2
- PDGFRB | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.101); catalogued as rs759684681, COSV99940794; called by muse, varscan2
- PDLIM3 | c.118C>T p.H40Y (on ENST00000284770 / NM_001257963.1; = p.H119Y on NM_014476.6) | Missense Mutation (SNP) | VAF 159/520 reads (31%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.975); catalogued as COSV52978642; called by muse, mutect2, varscan2
- PDZRN3 | c.1453G>C p.V485L | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs747518866; called by muse, mutect2, varscan2
- PEG3 | c.3793C>A p.P1265T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as rs909324686, COSV55645327, COSV55646290; called by muse, mutect2, varscan2
- PEX10 | c.394G>T p.G132W | Missense Mutation (SNP) | VAF 51/329 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV56580867; called by muse, mutect2, varscan2
- PGAM2 | c.184C>G p.R62G | Missense Mutation (SNP) | VAF 272/1110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs922606034; called by muse, mutect2, varscan2
- PGC | c.1036G>T p.G346* | Nonsense Mutation (SNP) | VAF 67/191 reads (35%) | catalogued as COSV57823628; called by muse, mutect2, varscan2
- PHACTR3 | c.692C>A p.P231H | Missense Mutation (SNP) | VAF 130/404 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV63028207; called by muse, mutect2, varscan2
- PHKB | c.1835A>G p.H612R | Missense Mutation (SNP) | VAF 44/303 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1189750988; called by muse, mutect2, varscan2
- PI16 | c.149C>A p.T50K | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as COSV65448281; called by muse, mutect2, varscan2
- PIEZO2 | c.5703C>G p.Y1901* | Nonsense Mutation (SNP) | VAF 90/212 reads (42%) | catalogued as COSV99555045; called by muse, mutect2, varscan2
- PIK3CG | c.971C>A p.P324Q | Missense Mutation (SNP) | VAF 95/344 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV63250351; called by muse, mutect2, varscan2
- PJA1 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 52/108 reads (48%) | catalogued as COSV100824740; called by muse, mutect2, varscan2
- PKHD1 | c.2825G>T p.G942V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV61885885; called by muse, mutect2
- PKHD1L1 | c.3796G>T p.G1266* | Nonsense Mutation (SNP) | VAF 41/115 reads (36%) | catalogued as COSV101006192; called by muse, mutect2, varscan2
- PKP1 | c.1850C>A p.S617Y | Missense Mutation (SNP) | VAF 206/467 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV55822269; called by muse, mutect2, varscan2
- PKP2 | c.1688+1G>T p.X563_splice | Splice Site (SNP) | VAF 37/113 reads (33%) | catalogued as CS102835; called by mutect2, varscan2
- PLBD2 | c.1523G>T p.R508L | Missense Mutation (SNP) | VAF 145/477 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745951952, COSV55107187; called by muse, mutect2, varscan2
- PLCE1 | c.4022G>T p.C1341F | Missense Mutation (SNP) | VAF 61/298 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.048); catalogued as rs759458474; called by muse, mutect2, varscan2
- PLCL1 | c.1972G>T p.D658Y | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV70820641; called by muse, mutect2, varscan2
- PLCZ1 | c.730G>T p.V244L | Missense Mutation (SNP) | VAF 74/199 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as rs1473420795; called by muse, mutect2, varscan2
- PLEC | c.4587G>T p.E1529D (on ENST00000322810 / NM_201380.4; = p.E1419D on NM_000445.5) | Missense Mutation (SNP) | VAF 107/372 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.836); catalogued as COSV59600111; called by muse, mutect2, varscan2
- PLG | c.1618G>T p.G540C | Missense Mutation (SNP) | VAF 70/310 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51981910; called by muse, mutect2, varscan2
- PLK5 | c.567G>T p.P189= | Splice Region (SNP) | VAF 112/198 reads (57%) | catalogued as rs773689990; called by muse, mutect2
- PNPLA7 | c.2651C>G p.P884R | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53007399; called by muse, mutect2, varscan2
- POF1B | c.1159C>A p.Q387K | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs1027909143; called by muse, mutect2, varscan2
- POLL | c.824G>T p.R275M | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100150074; called by muse, mutect2, varscan2
- POLR2G | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.496); catalogued as COSV57135026; called by muse, mutect2, varscan2
- POTEC | c.225C>A p.S75R | Missense Mutation (SNP) | VAF 213/824 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as COSV62800472, COSV62805903; called by muse, mutect2, varscan2
- POTEI | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 234/708 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs200337322; called by mutect2, varscan2
- POTEJ | c.2780C>A p.P927H | Missense Mutation (SNP) | VAF 277/1169 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV68639955; called by muse, varscan2
- PPFIA2 | c.2090G>T p.R697M | Missense Mutation (SNP) | VAF 118/345 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1247295933; called by muse, mutect2, varscan2
- PPFIA4 | c.1975G>T p.D659Y (on ENST00000447715; = p.D660Y on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 98/337 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.27); catalogued as COSV99690301; called by muse, mutect2, varscan2
- PRDM9 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 204/750 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.453); catalogued as COSV57013427; called by muse, mutect2, varscan2
- PREX1 | c.848C>A p.A283E | Missense Mutation (SNP) | VAF 119/440 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64247740; called by muse, mutect2, varscan2
- PRG4 | c.2492C>A p.P831H | Missense Mutation (SNP) | VAF 160/428 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV63356528; called by muse, mutect2, varscan2
- PRICKLE3 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.735); catalogued as rs782158023; called by muse, mutect2
- PRODH2 | c.566C>A p.T189N (on ENST00000301175; = p.T113N on NM_021232.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/250 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.355); catalogued as COSV99040616; called by muse, mutect2, varscan2
- PRPF38A | c.850C>T p.H284Y | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.775); catalogued as COSV99933516; called by muse, mutect2, varscan2
- PRX | c.4118G>A p.R1373Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as rs763294661, COSV52523514; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PSMC6 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 63/139 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV101471196; called by muse, mutect2, varscan2
- PSME4 | c.4154G>C p.G1385A | Missense Mutation (SNP) | VAF 48/159 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66364880; called by muse, mutect2, varscan2
- PTCH2 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 88/187 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV64709527; called by muse, mutect2, varscan2
- PTPRD | c.4013C>A p.P1338H | Missense Mutation (SNP) | VAF 82/173 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV61962282; called by muse, mutect2, varscan2
- PTPRD | c.3502G>T p.E1168* | Nonsense Mutation (SNP) | VAF 66/135 reads (49%) | catalogued as COSV61937662; called by muse, mutect2, varscan2
- PTPRQ | c.3768A>T p.L1256F (on ENST00000616559; = p.L1214F on NM_001145026.2) | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT tolerated (0.68); PolyPhen benign (0.181); catalogued as rs1291688801; called by muse, mutect2, varscan2
- PXDNL | c.3659T>A p.V1220D | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV100684969; called by muse, mutect2, varscan2
- PXDNL | c.3080C>G p.T1027S | Missense Mutation (SNP) | VAF 91/303 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV100684128; called by muse, mutect2, varscan2
- PXDNL | c.2829G>T p.E943D | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs147566293; called by muse, mutect2, varscan2
- RAB39B | c.557G>T p.W186L | Missense Mutation (SNP) | VAF 41/112 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as CM108101; called by muse, mutect2, varscan2
- RANBP2 | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 120/389 reads (31%) | catalogued as COSV51695545; called by muse, mutect2, varscan2
- RASAL2 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 87/380 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs199550328; called by muse, mutect2, varscan2
- RBAK | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV62331242; called by muse, mutect2, varscan2
- REEP3 | c.106-1G>T p.X36_splice | Splice Site (SNP) | VAF 37/127 reads (29%) | catalogued as rs368074557; called by muse, mutect2, varscan2
- REG3A | c.338C>A p.T113N | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV59410985; called by muse, mutect2, varscan2
- REG3A | c.119G>T p.C40F | Missense Mutation (SNP) | VAF 43/242 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59410912; called by muse, varscan2
- RELN | c.1803G>C p.W601C | Missense Mutation (SNP) | VAF 115/295 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100634258; called by muse, mutect2, varscan2
- RFFL | c.321G>T p.K107N | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52074250; called by muse, mutect2, varscan2
- RGS7 | c.449C>G p.A150G | Missense Mutation (SNP) | VAF 106/424 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV58557718; called by muse, mutect2, varscan2
- RNF2 | c.85C>A p.Q29K | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100835621; called by muse, mutect2, varscan2
- RNF31 | c.2875G>T p.A959S | Missense Mutation (SNP) | VAF 75/259 reads (29%) | SIFT tolerated (0.54); PolyPhen benign (0.146); catalogued as COSV100138254; called by muse, mutect2, varscan2
- ROBO1 | c.3046A>T p.I1016L | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.39); PolyPhen benign (0.358); catalogued as COSV71392655, COSV71397188; called by muse, mutect2, varscan2
- ROBO2 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 190/480 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765218623, COSV59936575; called by muse, mutect2, varscan2
- ROS1 | c.3528G>T p.W1176C | Missense Mutation (SNP) | VAF 60/241 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63855251; called by muse, mutect2, varscan2
- RP1L1 | c.5065C>A p.L1689M | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs763468681; called by muse, mutect2, varscan2
- RP1L1 | c.4225G>A p.E1409K | Missense Mutation (SNP) | VAF 88/614 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.234); catalogued as rs967433739; called by muse, varscan2
- RPGR | c.92G>T p.W31L | Missense Mutation (SNP) | VAF 39/174 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as CM1410801; called by muse, mutect2, varscan2
- RPH3A | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.9); PolyPhen benign (0.026); catalogued as COSV101231886; called by muse, mutect2, varscan2
- RPL15 | c.49G>T p.D17Y | Missense Mutation (SNP) | VAF 114/208 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1466906873; called by muse, mutect2, varscan2
- RPTOR | c.637C>T p.R213W | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as COSV60814499; called by muse, mutect2, varscan2
- RRP8 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766876049; called by muse, mutect2, varscan2
- RSAD2 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 63/287 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV101150028; called by muse, mutect2
- RUNX1T1 | c.1072G>T p.D358Y (on ENST00000265814 / NM_001198628.1; = p.D331Y on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/178 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56158111, COSV56162539; called by muse, mutect2, varscan2
- RXFP3 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 67/259 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV57504628; called by muse, varscan2
- RXFP3 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 134/458 reads (29%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV57503944, COSV57504531; called by muse, varscan2
- RYR2 | c.12579C>G p.C4193W | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as CM156360, COSV63676152; called by muse, mutect2, varscan2
- RYR3 | c.3418C>A p.R1140S | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs748509983, COSV66801387; called by muse, mutect2, varscan2
- RYR3 | c.12377C>A p.A4126E (on ENST00000389232; = p.A4127E on NM_001036.6) | Missense Mutation (SNP) | VAF 83/323 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66786898; called by muse, mutect2, varscan2
- SAGE1 | c.2363C>A p.T788N | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.381); catalogued as COSV61016976; called by muse, mutect2, varscan2
- SAMD4B | c.50G>C p.W17S | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV58753338; called by muse, mutect2, varscan2
- SBK2 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.017); catalogued as rs542381455, COSV60014998; called by muse, mutect2, varscan2
- SBNO1 | c.2569G>A p.D857N (on ENST00000420886; = p.D856N on NM_018183.5) | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV57345776; called by muse, mutect2, varscan2
- SCN5A | c.3432G>T p.M1144I (on ENST00000333535 / NM_198056.3; = p.M1143I on NM_000335.5) | Missense Mutation (SNP) | VAF 108/171 reads (63%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV61118294; called by muse, mutect2, varscan2
- SCRT2 | c.914C>A p.P305Q | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.053); catalogued as COSV55729340; called by muse, mutect2
- SCYL3 | c.1582G>A p.E528K (on ENST00000367770; = p.E474K on NM_020423.7) | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1558114484; called by muse, mutect2, varscan2
- SEC31A | c.1700G>T p.G567V (on ENST00000355196 / NM_001318120.1; = p.G528V on NM_016211.4) | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as COSV52344473; called by muse, mutect2, varscan2
- SEMA5A | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 69/179 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs202090123; called by muse, mutect2, varscan2
- SEPTIN8 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99736539; called by muse, mutect2, varscan2
- SERPIND1 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 28/177 reads (16%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs750892575; called by muse, mutect2, varscan2
- SEZ6L | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 93/511 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.417); catalogued as rs1335794595; called by muse, mutect2, varscan2
- SGCA | c.100C>A p.R34S | Missense Mutation (SNP) | VAF 166/602 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.327); catalogued as CM971332, COSV100006938; called by muse, mutect2, varscan2
- SGCA | c.101G>C p.R34P | Missense Mutation (SNP) | VAF 168/607 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); catalogued as CM163140, CM951149, COSV56249347; called by muse, mutect2, varscan2
- SGCG | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 52/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755404457, COSV54565762; called by muse, mutect2, varscan2
- SH3PXD2B | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 140/456 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1354278433; called by muse, mutect2, varscan2
- SHC4 | c.384C>A p.S128R | Missense Mutation (SNP) | VAF 90/314 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.497); catalogued as rs200771635, COSV60109691, COSV60110940; called by muse, mutect2, varscan2
- SLC10A4 | c.396C>A p.H132Q | Missense Mutation (SNP) | VAF 94/211 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.331); catalogued as rs1465798668; called by muse, mutect2, varscan2
- SLC12A3 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 55/365 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99344907; called by muse, mutect2, varscan2
- SLC14A1 | c.9C>A p.D3E | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs768136769; called by muse, mutect2, varscan2
- SLC16A5 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV61675339; called by muse, varscan2
- SLC17A4 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.196); catalogued as COSV64957478; called by muse, mutect2, varscan2
- SLC18A2 | c.1307G>T p.G436V | Missense Mutation (SNP) | VAF 143/409 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750968281; called by muse, mutect2, varscan2
- SLC22A1 | c.1577A>T p.K526M | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs748571557; called by muse, mutect2, varscan2
- SLC24A2 | c.747G>T p.L249F | Missense Mutation (SNP) | VAF 174/342 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53856378; called by muse, mutect2, varscan2
- SLC32A1 | c.743C>A p.T248K | Missense Mutation (SNP) | VAF 120/392 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.918); catalogued as COSV54146196; called by mutect2, varscan2
- SLC6A16 | c.1555G>A p.G519S | Missense Mutation (SNP) | VAF 205/575 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.954); catalogued as rs1321475223; called by muse, mutect2, varscan2
- SLC6A4 | c.698C>A p.T233K | Missense Mutation (SNP) | VAF 70/213 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as COSV104377579; called by muse, mutect2, varscan2
- SLC7A13 | c.417G>T p.L139F | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52536234; called by muse, mutect2, varscan2
- SLC7A3 | c.1282C>T p.L428F | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99979582; called by muse, mutect2, varscan2
- SLC9B1 | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 36/454 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99599059; called by muse, mutect2
- SLIT3 | c.82G>T p.G28W | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs924415374; called by muse, varscan2
- SMARCA4 | c.3582del p.Q1195Sfs*21 | Frame Shift Del (DEL) | VAF 273/674 reads (41%) | catalogued as COSV60789775, COSV60800634; called by mutect2, pindel, varscan2
- SMARCAL1 | c.1469G>T p.R490L | Missense Mutation (SNP) | VAF 161/619 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as COSV61919905; called by muse, mutect2, varscan2
- SNX32 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 146/520 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV57449456; called by muse, mutect2, varscan2
- SOBP | c.2504C>A p.A835E | Missense Mutation (SNP) | VAF 188/611 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV57996980; called by muse, mutect2, varscan2
- SORBS3 | c.1697G>T p.R566L | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV99531277; called by muse, varscan2
- SORCS1 | c.2390C>A p.P797Q | Missense Mutation (SNP) | VAF 91/269 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53853541; called by muse, mutect2, varscan2
- SORCS2 | c.1562A>T p.D521V | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1191729971; called by muse, mutect2, varscan2
- SORCS3 | c.1332C>A p.N444K | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as rs748524827; called by muse, mutect2, varscan2
- SORCS3 | c.2257G>C p.E753Q | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.932); catalogued as COSV63794514; called by muse, mutect2, varscan2
- SOS1 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 47/333 reads (14%) | catalogued as COSV67673938; called by muse, mutect2, varscan2
- SOX7 | c.773G>T p.G258V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs757143423; called by muse, mutect2, varscan2
- SPATA31A1 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.893); catalogued as rs762629549; called by muse, mutect2, varscan2
- SPEG | c.3232G>T p.G1078C | Missense Mutation (SNP) | VAF 110/355 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56669497; called by muse, mutect2, varscan2
- SPTA1 | c.4069G>T p.D1357Y | Missense Mutation (SNP) | VAF 104/299 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.766); catalogued as COSV63751723; called by muse, mutect2, varscan2
- SPTA1 | c.3069G>C p.Q1023H | Missense Mutation (SNP) | VAF 204/616 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63751424; called by muse, mutect2, varscan2
- SPTA1 | c.1300C>G p.Q434E | Missense Mutation (SNP) | VAF 159/463 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as COSV63761147; called by muse, mutect2, varscan2
- SPTB | c.2998C>A p.L1000M | Missense Mutation (SNP) | VAF 92/231 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.122); catalogued as COSV67634745; called by muse, mutect2, varscan2
- SPTBN4 | c.6230G>A p.G2077D | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100152301; called by muse, mutect2, varscan2
- SRFBP1 | c.19C>G p.L7V | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1464559952; called by muse, mutect2, varscan2
- SSPN | c.337G>T p.E113* | Nonsense Mutation (SNP) | VAF 79/247 reads (32%) | catalogued as COSV99658574; called by muse, mutect2, varscan2
- ST7 | c.818G>C p.R273P (on ENST00000265437 / NM_021908.3; = p.R250P on NM_018412.4) | Missense Mutation (SNP) | VAF 76/371 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV55392036; called by muse, mutect2, varscan2
- STAB2 | c.2742C>A p.C914* | Nonsense Mutation (SNP) | VAF 118/382 reads (31%) | catalogued as COSV66346198, COSV66346787; called by muse, mutect2, varscan2
- STAM2 | c.1180-1G>A p.X394_splice | Splice Site (SNP) | VAF 34/107 reads (32%) | catalogued as rs1410970149, COSV55730205; called by muse, mutect2, varscan2
- STRIP1 | c.669G>T p.M223I | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.021); catalogued as COSV63929780; called by muse, mutect2, varscan2
- SV2B | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 145/534 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57700728; called by muse, mutect2, varscan2
- SYN1 | c.1930G>T p.V644L | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1450465858; called by muse, mutect2, varscan2
- SYNDIG1L | c.637G>T p.A213S | Missense Mutation (SNP) | VAF 125/290 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779184482, COSV100526632; called by muse, mutect2, varscan2
- SYNGAP1 | c.1264G>T p.E422* | Nonsense Mutation (SNP) | VAF 188/708 reads (27%) | catalogued as rs1554121276; called by muse, mutect2, varscan2
- SYNGR1 | c.443G>T p.R148L | Missense Mutation (SNP) | VAF 178/487 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766039979, COSV53369106; called by muse, mutect2, varscan2
- SYNPO2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV100205375; called by muse, mutect2, varscan2
- SYNPO2 | c.838G>T p.G280* | Nonsense Mutation (SNP) | VAF 45/155 reads (29%) | catalogued as COSV61109626; called by muse, mutect2, varscan2
- SYT13 | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50073552; called by muse, mutect2, varscan2
- SYT14 | c.1349C>A p.P450Q | Missense Mutation (SNP) | VAF 73/352 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99656470; called by muse, mutect2, varscan2
- SYTL2 | c.473G>T p.R158M | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60355831; called by muse, mutect2, varscan2
- TAFA1 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 57/117 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as rs758404527; called by muse, mutect2, varscan2
- TBX15 | c.1580G>C p.R527T (on ENST00000369429 / NM_001330677.2; = p.R421T on NM_152380.3) | Missense Mutation (SNP) | VAF 89/609 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV99254947; called by muse, mutect2, varscan2
- TBX5 | c.612C>A p.H204Q | Missense Mutation (SNP) | VAF 173/511 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100091084; called by muse, mutect2, varscan2
- TCAF2 | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 95/802 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV62050747; called by muse, mutect2, varscan2
- TCF21 | c.359C>A p.T120K | Missense Mutation (SNP) | VAF 95/382 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52819117; called by muse, mutect2, varscan2
- TENM2 | c.439C>A p.R147S | Missense Mutation (SNP) | VAF 154/594 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.573); catalogued as rs752353786, COSV72852991; called by muse, mutect2, varscan2
- TENM2 | c.3077G>T p.R1026L (on ENST00000518659 / NM_001122679.2; = p.R794L on NM_001080428.3) | Missense Mutation (SNP) | VAF 87/295 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV101318020, COSV69134319; called by muse, mutect2, varscan2
- TENM3 | c.8054C>A p.A2685D | Missense Mutation (SNP) | VAF 104/362 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV69301437; called by muse, mutect2, varscan2
- TENM4 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.133); catalogued as rs546728680, COSV53620242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEP1 | c.4289A>T p.Q1430L | Missense Mutation (SNP) | VAF 94/265 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV53000658; called by muse, mutect2, varscan2
- TERB2 | c.317G>C p.W106S | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61650545; called by mutect2, varscan2
- TET1 | c.1703T>C p.M568T | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs770830999; called by muse, mutect2, varscan2
- TEX35 | c.460T>C p.C154R | Missense Mutation (SNP) | VAF 210/522 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV99275019; called by muse, mutect2, varscan2
- TEX37 | c.478C>T p.H160Y | Missense Mutation (SNP) | VAF 66/259 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.006); catalogued as rs375537087, COSV57556032, COSV57557050; called by muse, mutect2, varscan2
- TFEC | c.757C>T p.H253Y | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs1205356944; called by muse, mutect2, varscan2
- TGIF2LX | c.633C>G p.H211Q | Missense Mutation (SNP) | VAF 122/462 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.036); catalogued as COSV52213264; called by muse, mutect2, varscan2
- THAP1 | c.570A>T p.K190N | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as CD120401; called by muse, mutect2, varscan2
- THSD7B | c.4076G>C p.S1359T (on ENST00000272643; = p.S1357T on NM_001316349.2) | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs865831832; called by muse, mutect2, varscan2
- TIE1 | c.2424C>G p.I808M | Missense Mutation (SNP) | VAF 117/779 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV65249186; called by muse, mutect2, varscan2
- TLDC2 | c.450G>C p.W150C | Missense Mutation (SNP) | VAF 61/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1482832087; called by muse, mutect2, varscan2
- TLL1 | c.1673C>A p.S558Y | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50315534; called by muse, mutect2, varscan2
- TLR4 | c.1934C>A p.S645Y (on ENST00000355622 / NM_138554.5; = p.S605Y on NM_003266.4) | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.284); catalogued as rs560472197, COSV100842621; called by muse, mutect2, varscan2
- TLR9 | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62348206; called by muse, mutect2, varscan2
- TMEM132D | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 226/695 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.09); catalogued as rs773867246, COSV70596126, COSV70610579; called by muse, mutect2, varscan2
- TMEM132E | c.1423G>T p.V475F (on ENST00000321639; = p.V565F on NM_001304438.2) | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV58696991; called by muse, mutect2, varscan2
- TNXB | c.8854G>T p.V2952L (on ENST00000647633; = p.V2705L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/297 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV64486308; called by muse, mutect2, varscan2
- TP53 | c.421_423del p.C141del | In Frame Del (DEL) | VAF 86/305 reads (28%) | catalogued as COSV53637140; called by mutect2, pindel, varscan2
- TPH1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 62/322 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761126088; called by muse, mutect2, varscan2
- TRIM16L | c.126G>C p.R42S | Missense Mutation (SNP) | VAF 203/748 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV101192583; called by muse, mutect2, varscan2
- TRIM77 | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.836); catalogued as rs1253783454, COSV101242270; called by muse, mutect2
- TRPC1 | c.1014G>T p.Q338H (on ENST00000476941 / NM_001251845.2; = p.Q304H on NM_003304.4) | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV56428213; called by muse, mutect2, varscan2
- TRPM5 | c.2689C>A p.P897T | Missense Mutation (SNP) | VAF 40/203 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV50194808; called by muse, mutect2, varscan2
- TRPM6 | c.3330C>A p.H1110Q | Missense Mutation (SNP) | VAF 147/269 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs368851886; called by muse, mutect2, varscan2
- TRPV6 | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 133/473 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV63890904; called by muse, mutect2, varscan2
- TSHZ3 | c.1558del p.D521Ifs*10 | Frame Shift Del (DEL) | VAF 98/262 reads (37%) | catalogued as COSV99551832; called by mutect2, varscan2
- TSPYL6 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 120/584 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.559); catalogued as COSV57813174; called by muse, varscan2
- TTC26 | c.1069G>T p.D357Y | Missense Mutation (SNP) | VAF 63/235 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58274524; called by muse, mutect2, varscan2
- TXNDC15 | c.424G>T p.D142Y | Missense Mutation (SNP) | VAF 56/317 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs139383071; called by muse, mutect2, varscan2
- TYR | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 102/261 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.09); catalogued as COSV54475220; called by muse, mutect2, varscan2
- UCP1 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 34/280 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs769316561, COSV99530059; called by muse, mutect2, varscan2
- UGT2A2 | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1358635261; called by muse, mutect2, varscan2
- UNC13C | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs1473661188; called by muse, mutect2, varscan2
- UNC80 | c.4179G>T p.K1393N | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.994); catalogued as COSV55887262, COSV55913150; called by muse, varscan2
- UNC80 | c.4342G>T p.G1448C | Missense Mutation (SNP) | VAF 105/396 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as rs943426482, COSV99781344; called by muse, mutect2, varscan2
- UNCX | c.964G>A p.G322S | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs1312705326; called by muse, varscan2
- USP17L4 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.166); catalogued as rs1459352809; called by mutect2, varscan2
- USP32 | c.4739G>T p.G1580V | Missense Mutation (SNP) | VAF 47/194 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56267129; called by muse, mutect2, varscan2
- UTRN | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as COSV62335031; called by muse, mutect2, varscan2
- VCAN | c.6599C>T p.T2200I | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54102029; called by muse, mutect2, varscan2
- VMP1 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as COSV51873185; called by muse, mutect2
- VPS33A | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 75/201 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.009); catalogued as COSV57358359; called by muse, mutect2, varscan2
- VSIG4 | c.178C>A p.R60S | Missense Mutation (SNP) | VAF 87/198 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs751653148; called by muse, mutect2, varscan2
- VWDE | c.2075T>A p.L692Q | Missense Mutation (SNP) | VAF 63/213 reads (30%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.727); catalogued as COSV51725838; called by muse, mutect2, varscan2
- VWF | c.6893C>A p.T2298K | Missense Mutation (SNP) | VAF 154/624 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.806); catalogued as COSV99780180; called by muse, mutect2, varscan2
- VWF | c.5456-1G>T p.X1819_splice | Splice Site (SNP) | VAF 147/428 reads (34%) | catalogued as COSV99777831; called by muse, mutect2, varscan2
- VWF | c.2927G>T p.R976L | Missense Mutation (SNP) | VAF 179/656 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as COSV54610591; called by muse, mutect2, varscan2
- WDR81 | c.626C>T p.P209L | Missense Mutation (SNP) | VAF 90/381 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs200343855; called by muse, mutect2, varscan2
- WNT1 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 90/403 reads (22%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.035); catalogued as COSV99525296; called by muse, mutect2, varscan2
- WNT11 | c.217G>T p.A73S | Missense Mutation (SNP) | VAF 329/895 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs376706959; called by muse, mutect2, varscan2
- WT1 | c.1502C>A p.A501E | Missense Mutation (SNP) | VAF 60/363 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs749266841, COSV60086824, COSV60087202; called by muse, mutect2, varscan2
- XIRP2 | c.3949T>C p.W1317R (on ENST00000628543; = p.W1492R on NM_152381.6) | Missense Mutation (SNP) | VAF 55/171 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54704954; called by muse, mutect2, varscan2
- XPO1 | c.1798G>T p.V600F | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV68946129; called by muse, mutect2, varscan2
- XYLT1 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 87/546 reads (16%) | catalogued as COSV54485648; called by muse, mutect2, varscan2
- YEATS2 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV59363392; called by muse, mutect2, varscan2
- ZADH2 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 69/199 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1445520579; called by muse, mutect2, varscan2
- ZC3H11A | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.983); catalogued as COSV59750698; called by muse, mutect2, varscan2
- ZC3H6 | c.377G>T p.G126V | Missense Mutation (SNP) | VAF 51/138 reads (37%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV59669674; called by muse, mutect2, varscan2
- ZDHHC11 | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 61/600 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52062012; called by muse, varscan2
- ZEB2 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 67/220 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.135); catalogued as COSV100356712; called by muse, mutect2, varscan2
- ZFHX4 | c.4703A>T p.K1568M | Missense Mutation (SNP) | VAF 47/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50532233; called by muse, mutect2, varscan2
- ZFHX4 | c.8491G>A p.G2831R | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs554869311, COSV50704827, COSV99268698; called by muse, mutect2, varscan2
- ZFP1 | c.16-2A>T p.X6_splice | Splice Site (SNP) | VAF 41/222 reads (18%) | catalogued as COSV60033672; called by muse, mutect2, varscan2
- ZFPM2 | c.2481C>G p.D827E | Missense Mutation (SNP) | VAF 97/373 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV65872371; called by muse, mutect2, varscan2
- ZIC3 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 132/499 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV54975768; called by muse, mutect2, varscan2
- ZIM3 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.232); catalogued as rs1209117682, COSV99518008; called by muse, mutect2, varscan2
- ZMAT1 | c.1819G>T p.E607* | Nonsense Mutation (SNP) | VAF 41/185 reads (22%) | catalogued as COSV100858822; called by muse, varscan2
- ZMAT1 | c.1805A>G p.H602R | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.059); catalogued as rs372063692, COSV65657672; called by muse, varscan2
- ZNF284 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.588); catalogued as rs377613949; called by muse, mutect2, varscan2
- ZNF285 | c.1049G>A p.G350E | Missense Mutation (SNP) | VAF 87/238 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs1462307043; called by muse, mutect2, varscan2
- ZNF33A | c.2033G>T p.G678V (on ENST00000458705 / NM_006974.3; = p.G679V on NM_006954.2) | Missense Mutation (SNP) | VAF 45/152 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.23); catalogued as rs766382393, COSV100275834; called by muse, mutect2, varscan2
- ZNF45 | c.419A>T p.Y140F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.011); catalogued as COSV54193263; called by muse, mutect2
- ZNF467 | c.1634G>T p.C545F | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57374220; called by muse, mutect2, varscan2
- ZNF479 | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 75/226 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV100482716; called by muse, mutect2, varscan2
- ZNF521 | c.1547C>A p.P516H | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.979); catalogued as COSV64124861; called by muse, mutect2, varscan2
- ZNF571 | c.967A>G p.T323A | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as rs768648883; called by muse, mutect2, varscan2
- ZNF585A | c.1119G>T p.Q373H (on ENST00000292841 / NM_001288800.2; = p.Q318H on NM_152655.3) | Missense Mutation (SNP) | VAF 43/193 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53066999; called by muse, mutect2, varscan2
- ZNF628 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 84/354 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs926712381; called by muse, mutect2, varscan2
- ZNF711 | c.133G>T p.V45F | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV52153663; called by muse, varscan2
- ZNF726 | c.1958G>C p.C653S | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs543650451; called by muse, mutect2, varscan2
- ZNF727 | c.1252C>A p.H418N | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs761366126, COSV101407008, COSV101407018; called by muse, mutect2, varscan2
- ZNF765 | c.1412G>T p.C471F | Missense Mutation (SNP) | VAF 82/274 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs762554302; called by muse, mutect2
- ZNF804A | c.2864C>T p.P955L | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV56443184; called by muse, mutect2, varscan2
- ZNF831 | c.745G>T p.G249C | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs760029924, COSV64038403; called by muse, mutect2, varscan2
- ZNF845 | c.997G>T p.G333C | Missense Mutation (SNP) | VAF 68/309 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101508952; called by muse, mutect2, varscan2
- ZNRF4 | c.860G>T p.R287L | Missense Mutation (SNP) | VAF 157/281 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV55774484; called by muse, mutect2, varscan2
- ZZZ3 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as rs1324918070; called by muse, mutect2
- A2M | c.3655G>T p.A1219S | Missense Mutation (SNP) | VAF 231/634 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ABCA6 | c.1769A>T p.E590V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); called by muse, mutect2
- ABCA9 | c.3223G>C p.V1075L | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ABCA9 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCB5 | c.53+2T>A p.X18_splice | Splice Site (SNP) | VAF 57/223 reads (26%) | called by muse, mutect2, varscan2
- ABCC12 | c.3254C>A p.T1085N | Missense Mutation (SNP) | VAF 66/338 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- ABCC12 | c.17C>A p.P6H | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- ABCC2 | c.1531-1G>T p.X511_splice | Splice Site (SNP) | VAF 46/295 reads (16%) | called by muse, mutect2, varscan2
- ABCC9 | c.3214C>A p.L1072I | Missense Mutation (SNP) | VAF 78/325 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ABCC9 | c.2651C>T p.A884V | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ABCC9 | c.1330G>T p.G444C | Missense Mutation (SNP) | VAF 45/241 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- ABCC9 | c.805G>T p.E269* | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | called by muse, mutect2, varscan2
- ABCG5 | c.319G>T p.G107W | Missense Mutation (SNP) | VAF 164/621 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ABR | c.890G>T p.G297V (on ENST00000302538 / NM_021962.5; = p.G260V on NM_001092.5) | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- ACCS | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 23/153 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ACTA1 | c.1073G>C p.W358S | Missense Mutation (SNP) | VAF 169/451 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACTRT1 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 58/246 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ADA | c.436del p.V146Sfs*33 | Frame Shift Del (DEL) | VAF 153/597 reads (26%) | called by mutect2, pindel, varscan2
- ADA | c.132G>T p.E44D | Missense Mutation (SNP) | VAF 129/479 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAD1 | c.1041A>G p.I347M | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ADAM10 | c.1906A>T p.R636* | Nonsense Mutation (SNP) | VAF 142/419 reads (34%) | called by muse, mutect2, varscan2
- ADAM2 | c.1226T>C p.I409T | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- ADAM22 | c.445G>T p.V149F | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADAM22 | c.489C>A p.D163E | Missense Mutation (SNP) | VAF 41/281 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS13 | c.2314G>T p.A772S | Missense Mutation (SNP) | VAF 159/377 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ADAMTS17 | c.3159G>T p.Q1053H | Missense Mutation (SNP) | VAF 192/650 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS17 | c.3028G>T p.E1010* | Nonsense Mutation (SNP) | VAF 49/168 reads (29%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.1583C>A p.P528Q | Missense Mutation (SNP) | VAF 86/246 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ADAMTS20 | c.1582C>A p.P528T | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ADAMTS4 | c.900C>A p.N300K | Missense Mutation (SNP) | VAF 121/357 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ADCY2 | c.663G>T p.Q221H | Missense Mutation (SNP) | VAF 77/247 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ADCY8 | c.2054G>T p.R685I | Missense Mutation (SNP) | VAF 102/404 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); called by muse, varscan2
- ADCY9 | c.117del p.N40Tfs*59 | Frame Shift Del (DEL) | VAF 39/231 reads (17%) | called by mutect2, pindel, varscan2
- ADD3 | c.875G>A p.R292K | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ADGRA1 | c.851C>A p.T284N | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.048); called by muse, varscan2
- ADGRA1 | c.1415G>T p.C472F | Missense Mutation (SNP) | VAF 85/260 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ADGRB1 | c.3337G>T p.V1113L | Missense Mutation (SNP) | VAF 92/336 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, varscan2
- ADGRG4 | c.408C>A p.F136L | Missense Mutation (SNP) | VAF 84/253 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRG4 | c.567C>G p.D189E | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRG4 | c.5501C>A p.T1834K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ADGRG4 | c.6884G>A p.S2295N | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, varscan2
- ADGRL2 | c.2011G>T p.E671* (on ENST00000370717 / NM_001366005.1; = p.E658* on NM_012302.4) | Nonsense Mutation (SNP) | VAF 70/131 reads (53%) | called by muse, mutect2, varscan2
- ADGRL3 | c.3810C>A p.N1270K (on ENST00000506720 / NM_001322402.2; = p.N1202K on NM_015236.6) | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ADGRL3 | c.4578C>A p.Y1526* (on ENST00000506720 / NM_001322402.2; = p.Y1415* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 53/300 reads (18%) | called by muse, mutect2, varscan2
- ADGRV1 | c.485del p.G162Afs*22 | Frame Shift Del (DEL) | VAF 14/50 reads (28%) | called by mutect2, pindel, varscan2
- ADIPOQ | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- AFAP1L2 | c.352G>T p.E118* | Nonsense Mutation (SNP) | VAF 73/225 reads (32%) | called by muse, mutect2, varscan2
- AFF2 | c.1769G>C p.S590T | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AFP | c.837G>T p.Q279H | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.71); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- AGBL1 | c.1181A>T p.H394L | Missense Mutation (SNP) | VAF 15/190 reads (8%) | SIFT tolerated (0.63); PolyPhen benign (0.007); called by muse, mutect2
- AHCTF1 | c.2046G>C p.E682D (on ENST00000366508; = p.E656D on NM_015446.5) | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- AHNAK | c.14638G>T p.G4880C | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHNAK | c.14292del p.N4765Tfs*14 | Frame Shift Del (DEL) | VAF 72/334 reads (22%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.14962C>G p.L4988V | Missense Mutation (SNP) | VAF 75/179 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- AHSG | c.970G>T p.V324F | Missense Mutation (SNP) | VAF 113/389 reads (29%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- AIFM3 | c.1507C>T p.Q503* | Nonsense Mutation (SNP) | VAF 92/672 reads (14%) | called by muse, mutect2, varscan2
- AK5 | c.16G>T p.A6S | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- AKAP17A | c.1186G>T p.E396* | Nonsense Mutation (SNP) | VAF 63/140 reads (45%) | called by muse, mutect2, varscan2
- AKR1C1 | c.451G>T p.V151L | Missense Mutation (SNP) | VAF 68/255 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKR1C4 | c.860A>C p.Q287P | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- ALK | c.4047C>A p.D1349E | Missense Mutation (SNP) | VAF 72/347 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.421); called by muse, varscan2
- ALMS1 | c.784G>T p.E262* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- ALOX12B | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 80/282 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- ALPK1 | c.620dup p.M209Dfs*24 | Frame Shift Ins (INS) | VAF 19/101 reads (19%) | called by mutect2, pindel, varscan2
- AMIGO1 | c.1477G>C p.V493L | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- AMOT | c.3164C>A p.P1055H (on ENST00000371959 / NM_001113490.1; = p.P646H on NM_133265.3) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- AMY2B | c.1220+1G>T p.X407_splice | Splice Site (SNP) | VAF 40/517 reads (8%) | called by muse, mutect2
- ANAPC7 | c.1483G>T p.G495* | Nonsense Mutation (SNP) | VAF 70/204 reads (34%) | called by muse, mutect2, varscan2
- ANGEL1 | c.1457del p.G486Afs*41 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | called by mutect2, pindel, varscan2
- ANK2 | c.3029A>T p.K1010M | Missense Mutation (SNP) | VAF 137/432 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.8825G>T p.G2942V | Missense Mutation (SNP) | VAF 51/171 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD1 | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ANKRD12 | c.4505C>A p.A1502D | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- ANKRD2 | c.311G>T p.R104L | Missense Mutation (SNP) | VAF 52/303 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ANKRD52 | c.2365T>A p.Y789N | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT tolerated (0.93); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANKS1B | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- APEX2 | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APLNR | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 78/257 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOBR | c.2728G>T p.A910S (on ENST00000431282; = p.A919S on NM_018690.4) | Missense Mutation (SNP) | VAF 42/181 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- ARHGAP25 | c.1919A>T p.K640M (on ENST00000409202 / NM_001007231.3; = p.K632M on NM_014882.3) | Missense Mutation (SNP) | VAF 83/380 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- ARHGAP27 | c.2174-7G>T | Splice Region (SNP) | VAF 38/138 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.189+1G>T p.X63_splice | Splice Site (SNP) | VAF 111/283 reads (39%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.501+4G>T | Splice Region (SNP) | VAF 70/191 reads (37%) | called by muse, mutect2, varscan2
- ARHGAP33 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 109/293 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGAP40 | c.1840G>T p.E614* | Nonsense Mutation (SNP) | VAF 89/305 reads (29%) | called by muse, mutect2, varscan2
- ARHGAP6 | c.2730G>T p.Q910H (on ENST00000337414 / NM_013427.3; = p.Q707H on NM_013423.3) | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGEF15 | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 129/374 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ARHGEF17 | c.3527G>T p.R1176L | Missense Mutation (SNP) | VAF 70/295 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGEF37 | c.658G>T p.A220S | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ARID1B | c.6546G>T p.M2182I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ARRDC3 | c.1152G>T p.Q384H | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARX | c.1074-1G>T p.X358_splice | Splice Site (SNP) | VAF 156/1196 reads (13%) | called by muse, mutect2, varscan2
- ASAP1 | c.2962G>T p.D988Y | Missense Mutation (SNP) | VAF 74/272 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ASCC3 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 21/91 reads (23%) | called by muse, mutect2, varscan2
- ASRGL1 | c.749T>A p.L250Q | Missense Mutation (SNP) | VAF 148/434 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ATG2A | c.3530G>T p.R1177L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- ATG4A | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- ATL3 | c.287dup p.L96Ffs*3 | Frame Shift Ins (INS) | VAF 32/101 reads (32%) | called by mutect2, pindel, varscan2
- ATN1 | c.2500G>T p.E834* | Nonsense Mutation (SNP) | VAF 106/252 reads (42%) | called by muse, mutect2, varscan2
- ATP11C | c.3304C>A p.L1102M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ATP12A | c.2930A>C p.Q977P | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP1A3 | c.2662G>A p.G888S (on ENST00000545399 / NM_001256214.2; = p.G875S on NM_152296.5) | Missense Mutation (SNP) | VAF 260/717 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- ATP1A4 | c.1699C>A p.L567M | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- ATP2A1 | c.1183G>A p.V395I | Missense Mutation (SNP) | VAF 123/371 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATP2B3 | c.1802C>A p.A601D | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP2B3 | c.3035G>A p.G1012D | Missense Mutation (SNP) | VAF 82/312 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ATP2B3 | c.3170C>A p.T1057N | Missense Mutation (SNP) | VAF 46/146 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.162); called by muse, varscan2
- ATRN | c.2108G>T p.R703I | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.433); called by muse, mutect2, varscan2
2,074 further variants in this file (1,203 protein-altering or splice-affecting, 542 silent, 329 other) are not listed here.
